OHSU case 4038 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/10b49b21-bae9-46c2-ae9e-e31ecf0a814a

Biospecimens (1 sample)
- Sample 2528D: Tissue type: Tumor; Preservation method: Snap Frozen.
